Somatic mutation profile of tumor specimen TCGA-XV-AB01-06A (aliquot TCGA-XV-AB01-06A-12D-A401-08) from TCGA case TCGA-XV-AB01, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 54.9 years (20,058 days).
Specimen TCGA-XV-AB01-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b35d933a-a208-4429-b95e-2be399c3525e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XV-AB01-10A (Blood Derived Normal), aliquot TCGA-XV-AB01-10A-01D-A401-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9253e93d-b708-458c-beb6-8940ab158224

The open-access MAF lists 227 somatic variants for this specimen: 164 protein-altering or splice-affecting, 61 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 151, Silent 61, In Frame Del 5, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 1, Intron 1, Nonstop Mutation 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CTNNB1 | c.133_135del p.S45del | In Frame Del (DEL) | VAF 14/31 reads (45%) | hotspot (GDC flag); catalogued as rs587776850; ClinVar: pathogenic / other; called by mutect2, pindel, varscan2
- ABCB1 | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773542500; called by muse, mutect2, varscan2
- ADAM2 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775998804, COSV55860658; called by muse, mutect2, varscan2
- ADAMTS14 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.689); catalogued as COSV64599380; called by muse, mutect2, varscan2
- ADCY10 | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0.236); catalogued as COSV63244828; called by muse, mutect2, varscan2
- AKR1D1 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV54341157, COSV99652795; called by muse, mutect2, varscan2
- ALCAM | c.1609C>T p.L537F | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100065335; called by muse, mutect2, varscan2
- ANO5 | c.2138C>A p.T713N | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1487599092; called by muse, mutect2, varscan2
- APOB | c.5247G>A p.M1749I | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV51925904; called by muse, mutect2, varscan2
- AQP6 | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as rs1303497781; called by muse, mutect2, varscan2
- ARHGAP36 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV52266407, COSV52267326; called by muse, mutect2, varscan2
- ARSF | c.509T>A p.V170D | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV63839324; called by muse, mutect2, varscan2
- BCR | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); catalogued as rs760569480, COSV59930825; called by muse, mutect2, varscan2
- BRINP2 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs755472407, COSV100838014, COSV64176192; called by muse, mutect2, varscan2
- C12orf50 | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs112656239, COSV53895894; called by muse, mutect2, varscan2
- CCDC68 | c.841C>T p.L281F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV61603293; called by muse, mutect2, varscan2
- CD1D | c.327C>T p.S109= | Splice Region (SNP) | VAF 12/40 reads (30%) | catalogued as rs1199062111, COSV63808883; called by muse, mutect2, varscan2
- CDR1 | c.590G>A p.R197K | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.225); catalogued as COSV100983473, COSV65164565; called by muse, mutect2, varscan2
- CFHR1 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as rs753093577, COSV57626056; called by muse, mutect2, varscan2
- CLVS1 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs373908809; called by muse, mutect2, varscan2
- CNGA3 | c.1405G>T p.A469S | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs117522010, CM085330, COSV55626572; called by muse, mutect2, varscan2
- CNTN5 | c.2825G>A p.G942E | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1436874415, COSV54275052, COSV99681181; called by muse, mutect2, varscan2
- COL21A1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55161262; called by muse, mutect2, varscan2
- CSF2RB | c.1661C>T p.T554M | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as rs146859739; called by muse, mutect2, varscan2
- CSMD3 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV52164534; called by muse, mutect2, varscan2
- DDI1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV56372611; called by muse, mutect2, varscan2
- DISP2 | c.2328G>A p.W776* | Nonsense Mutation (SNP) | VAF 25/89 reads (28%) | catalogued as rs1395855873; called by muse, mutect2, varscan2
- DMC1 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs745397961, COSV53258386; called by muse, mutect2, varscan2
- DUSP12 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 41/100 reads (41%) | catalogued as rs751083631, COSV63411256; called by muse, mutect2, varscan2
- EPS15L1 | c.2284G>A p.G762R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.708); catalogued as rs1307938620; called by muse, mutect2, varscan2
- F8 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs957046115; called by muse, mutect2, varscan2
- FBN3 | c.7753C>T p.R2585C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.511); catalogued as rs760490060, COSV54459122; called by muse, mutect2, varscan2
- FLT3 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as COSV104385725; called by muse, mutect2, varscan2
- FOXO1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1034299550, COSV65425761; called by muse, mutect2, varscan2
- GJA5 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54784085; called by muse, mutect2, varscan2
- H3C13 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); catalogued as rs782549707; called by muse, mutect2, varscan2
- HERC2 | c.14060C>T p.S4687L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs772969358; called by muse, mutect2, varscan2
- IKZF1 | c.1454G>A p.G485D | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58781407; called by muse, mutect2, varscan2
- KHDRBS3 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.228); catalogued as rs868022944; called by muse, mutect2, varscan2
- KIAA1109 | c.7462G>A p.A2488T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs765634631; called by muse, mutect2, varscan2
- LILRA4 | c.1220C>G p.S407C | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52491052; called by muse, varscan2
- LRRC27 | c.1265C>T p.S422L | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs748794466, COSV63996627; called by muse, mutect2, varscan2
- LRRC3B | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV101185673; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1126G>A p.G376S | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.999); catalogued as rs1294201959; called by muse, mutect2
- MGAM | c.3406G>A p.E1136K | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866353991, COSV72074697; called by muse, mutect2, varscan2
- MINAR1 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as COSV59586573; called by muse, mutect2, varscan2
- MSI1 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs759088687; called by muse, mutect2, varscan2
- MUC16 | c.2615C>T p.P872L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV67460673; called by muse, mutect2, varscan2
- MUC16 | c.674G>A p.R225K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); catalogued as rs894065188; called by muse, mutect2, varscan2
- MYH1 | c.3859G>A p.E1287K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs1249269755, COSV56848108; called by muse, mutect2, varscan2
- NGEF | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.932); catalogued as COSV50933710; called by muse, mutect2, varscan2
- NTSR1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100980624; called by muse, mutect2, varscan2
- OR10A6 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs149192400, COSV59165745; called by muse, mutect2, varscan2
- OR1G1 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as COSV61030202; called by muse, mutect2
- OR2T2 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.936); catalogued as rs768905008; called by muse, mutect2, varscan2
- OR6B3 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100096812; called by muse, mutect2
- OSGEP | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs374503423; called by muse, mutect2, varscan2
- PCDHA13 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs782410675; called by muse, mutect2, varscan2
- PCDHA6 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.119); catalogued as rs782133322, COSV65351142; called by muse, mutect2, varscan2
- PHKA1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59805806; called by muse, mutect2, varscan2
- PKHD1L1 | c.5635G>A p.E1879K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.232); catalogued as COSV65749542; called by muse, mutect2, varscan2
- PLB1 | c.3658C>T p.P1220S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.622); catalogued as rs1321242089; called by muse, mutect2, varscan2
- PNPLA7 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.89); catalogued as rs1430085374; called by muse, mutect2, varscan2
- POM121L12 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV101374961, COSV68692749; called by muse, mutect2, varscan2
- POP4 | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1187528012; called by muse, mutect2, varscan2
- PRB4 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.391); catalogued as COSV54396145; called by muse, varscan2
- PRKCQ | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV54111039; called by muse, mutect2, varscan2
- RIPPLY3 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as rs769944724, COSV61567209; called by muse, mutect2, varscan2
- ROBO3 | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67300671; called by muse, mutect2, varscan2
- SAMD9 | c.3788C>T p.S1263F | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV66073254, COSV66075209; called by muse, mutect2, varscan2
- SCN7A | c.2402C>T p.T801I | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.522); catalogued as rs1203840973, COSV69271156, COSV69273023; called by muse, mutect2, varscan2
- SETBP1 | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV56321785; called by muse, mutect2, varscan2
- SETBP1 | c.1817C>T p.S606F | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56331970; called by muse, mutect2, varscan2
- SETBP1 | c.3517C>T p.L1173F | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56334704; called by muse, mutect2, varscan2
- SH2D7 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.738); catalogued as rs367693089; called by muse, mutect2, varscan2
- SLITRK6 | c.979C>A p.P327T | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs1192823462; called by muse, mutect2, varscan2
- SOCS5 | c.458_461del p.E153Gfs*5 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as rs1558414783; called by mutect2, pindel, varscan2
- SPTAN1 | c.5773C>T p.R1925C | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs267602137, COSV63986894; called by muse, mutect2, varscan2
- SRRM3 | c.698G>A p.R233K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV58390629; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.740G>A p.R247K | Missense Mutation (SNP) | VAF 28/83 reads (34%) | PolyPhen possibly damaging (0.855); catalogued as rs774760454, COSV100603094, COSV59563701; called by muse, mutect2, varscan2
- SYT10 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as rs1466482159, COSV57343627; called by muse, mutect2, varscan2
- TC2N | c.1269G>A p.M423I | Missense Mutation (SNP) | VAF 78/270 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as COSV61746521; called by muse, mutect2, varscan2
- TGM6 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs757415452, COSV99172704; called by muse, mutect2, varscan2
- TPBG | c.1262G>T p.*421Lext*15 | Nonstop Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as rs1249882305; called by muse, mutect2, varscan2
- TRAV5 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs1566650517; called by muse, mutect2, varscan2
- TRIM60 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61970398; called by muse, mutect2, varscan2
- TRPM5 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs532348335; called by muse, mutect2, varscan2
- TSC2 | c.5394_5396del p.S1799del | In Frame Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs796053480; called by pindel, varscan2
- TTN | c.78601G>A p.A26201T (on ENST00000591111; = p.A18777T on NM_003319.4) | Missense Mutation (SNP) | VAF 25/50 reads (50%) | PolyPhen probably damaging (0.997); catalogued as rs1298853376; called by muse, mutect2, varscan2
- TTN | c.44206G>A p.D14736N (on ENST00000591111; = p.D7312N on NM_003319.4) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | PolyPhen probably damaging (0.998); catalogued as rs757542062, COSV60170585; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUFM | c.1350_1352del p.K450del | In Frame Del (DEL) | VAF 32/112 reads (29%) | catalogued as rs778401493; called by pindel, varscan2
- UGT2B15 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.208); catalogued as rs1468376670; called by muse, mutect2, varscan2
- VARS1 | c.3550C>T p.R1184C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs140736335; called by muse, mutect2, varscan2
- ZC3HAV1L | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1280213909; called by muse, mutect2, varscan2
- ZNF174 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1490349182, COSV51904556; called by muse, mutect2, varscan2
- ZNF208 | c.3487C>T p.H1163Y | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV68111321; called by muse, mutect2, varscan2
- ZNF285 | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58409998; called by muse, mutect2, varscan2
- ZNF560 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV56870118; called by muse, mutect2, varscan2
- AADACL4 | c.890G>A p.R297K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ADCY8 | c.2782C>T p.L928F | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRG4 | c.1892C>T p.S631F | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK3 | c.4201-2A>T p.X1401_splice (on ENST00000280772 / NM_001320874.2; = p.X535_splice on NM_001149.3) | Splice Site (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- BBS7 | c.1667G>A p.S556N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CDH8 | c.53T>A p.I18K | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CENPJ | c.539C>T p.T180I | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CORIN | c.2453C>T p.S818F | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSF2RB | c.2476C>T p.P826S | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CYP3A43 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DENND4C | c.5790_5791del p.E1930Dfs*3 (on ENST00000434457 / NM_001330640.2; = p.E1881Dfs*3 on NM_017925.7) | Frame Shift Del (DEL) | VAF 26/86 reads (30%) | called by pindel, varscan2
- DPP8 | c.1243G>T p.V415L (on ENST00000341861 / NM_001320875.2; = p.V399L on NM_017743.6) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DRD5 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- ELAPOR1 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ENPP6 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- EPHA8 | c.2636G>T p.R879L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- FAT3 | c.2653A>T p.I885F | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- FLG2 | c.1975G>A p.G659R | Missense Mutation (SNP) | VAF 95/325 reads (29%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- FMN2 | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FOXD4L4 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by mutect2, varscan2
- FUT5 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KDM3A | c.3490A>G p.I1164V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- KLHL13 | c.1481G>A p.G494E | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL17 | c.1501_1503del p.E501del | In Frame Del (DEL) | VAF 19/37 reads (51%) | called by mutect2, pindel, varscan2
- LCN10 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LENG8 | c.2056C>T p.L686F | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC74A | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- MAPKBP1 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MET | c.1379G>A p.G460D | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MROH2B | c.1732C>T p.L578F | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.25208C>T p.T8403I | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- MXRA5 | c.4234G>A p.E1412K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- MYCBP2 | c.12133C>T p.L4045F (on ENST00000357337; = p.L4083F on NM_015057.5) | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NEK11 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NMNAT2 | c.126T>G p.I42M | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- OR4F17 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 51/321 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR5M10 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR6B1 | c.557A>T p.N186I | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- OR6C76 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OTOF | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCLO | c.13570C>T p.P4524S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDYN | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- PHF23 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- PIWIL1 | c.650G>A p.R217K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- PSPH | c.374T>C p.I125T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAPGEF6 | c.662C>G p.T221R | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- RING1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- RNF207 | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2
- SLC7A11 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SMG8 | c.1522C>T p.H508Y | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SPTBN4 | c.1126A>G p.I376V | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- STS | c.1645C>T p.L549F | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SYTL5 | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TEX15 | c.4676C>T p.S1559L (on ENST00000256246; = p.S1942L on NM_001350162.2) | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- TFAP2A | c.850A>T p.K284* (on ENST00000482890; = p.K276* on NM_001032280.3) | Nonsense Mutation (SNP) | VAF 16/80 reads (20%) | called by muse, mutect2, varscan2
- TMC5 | c.2137T>C p.W713R (on ENST00000396229 / NM_001105248.1; = p.W467R on NM_024780.5) | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM131 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRAV36DV7 | c.266A>T p.K89I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- TRAV8-2 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- TTN | c.97892G>A p.G32631D (on ENST00000591111; = p.G25207D on NM_003319.4) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- USP11 | c.1222C>T p.L408F (on ENST00000218348; = p.L365F on NM_001371072.1) | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZHX1 | c.446A>T p.N149I | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- ZNF17 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF831 | c.2599G>T p.G867W | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZSCAN21 | c.888_890del p.R297del | In Frame Del (DEL) | VAF 23/59 reads (39%) | called by mutect2, pindel, varscan2
- ACSS1 | c.2022C>T p.I674= | Silent (SNP) | VAF 34/123 reads (28%) | called by muse, mutect2, varscan2
- ADCY8 | c.1138C>A p.R380= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs376386996; called by muse, mutect2, varscan2
- AMDHD2 | c.888C>T p.I296= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs376314432; called by muse, mutect2, varscan2
- BCL2L14 | c.303G>A p.E101= | Silent (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
- CCNB3 | c.783C>T p.F261= | Silent (SNP) | VAF 30/49 reads (61%) | called by muse, mutect2, varscan2
- CLIP4 | c.1068G>A p.R356= | Silent (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- CNGA4 | c.864G>A p.K288= | Silent (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- DDC | c.432C>T p.I144= | Silent (SNP) | VAF 17/111 reads (15%) | called by muse, mutect2, varscan2
- DEPDC5 | c.315G>A p.K105= | Silent (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2, varscan2
- DIDO1 | c.6033C>T p.F2011= | Silent (SNP) | VAF 35/128 reads (27%) | catalogued as rs754805521; called by muse, mutect2, varscan2
- DNAH11 | c.10629C>T p.L3543= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs533054368, COSV60988718; called by muse, mutect2, varscan2
- EFHC2 | c.624G>A p.E208= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs774216331, COSV101375546; called by muse, mutect2, varscan2
- ERCC6L | c.1878G>A p.E626= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs773027699; called by muse, mutect2, varscan2
- ERICH3 | c.1239G>A p.R413= | Silent (SNP) | VAF 47/106 reads (44%) | catalogued as COSV58619687; called by muse, mutect2, varscan2
- ESRRB | c.1089C>T p.V363= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99834897; called by muse, mutect2, varscan2
- FAM47A | c.675G>A p.P225= | Silent (SNP) | VAF 40/70 reads (57%) | catalogued as rs776044393, COSV60496205; called by muse, mutect2, varscan2
- FAT4 | c.9120G>A p.T3040= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs749702080, COSV58696098; called by muse, mutect2, varscan2
- FLNB | c.3657G>A p.R1219= | Silent (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- GPR137C | c.954G>A p.V318= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs752666044; called by muse, mutect2, varscan2
- HCRTR2 | c.195C>T p.F65= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as COSV63796144; called by muse, mutect2, varscan2
- HIRA | c.309C>T p.I103= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs199963493; called by muse, mutect2, varscan2
- IGSF9B | c.2688C>T p.N896= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs749283493, COSV58069721; called by muse, mutect2, varscan2
- KCNK17 | c.795C>T p.S265= | Silent (SNP) | VAF 30/169 reads (18%) | called by muse, mutect2, varscan2
- KMT2D | c.10668C>T p.F3556= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs1027983394, COSV99040291; called by muse, mutect2
- KRTAP10-7 | c.921C>T p.S307= | Silent (SNP) | VAF 39/122 reads (32%) | catalogued as rs1463742720; called by muse, mutect2, varscan2
- LILRB1 | c.300G>A p.K100= (on ENST00000427581; = p.K64= on NM_006669.6) | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV100207043; called by muse, mutect2, varscan2
- LNX2 | c.1105C>T p.L369= | Silent (SNP) | VAF 49/145 reads (34%) | called by muse, mutect2, varscan2
- LRP4 | c.1728C>T p.T576= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1186084709; called by muse, mutect2, varscan2
- MAP7D2 | c.348G>A p.R116= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs900080753, COSV101107594; called by muse, mutect2, varscan2
- MINAR1 | c.2542C>T p.L848= | Silent (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- MXRA5 | c.7737C>T p.P2579= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- MYLK | c.5040C>T p.F1680= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs927213113; called by muse, mutect2, varscan2
- NAGS | c.1311G>A p.G437= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as rs762358574; called by muse, varscan2
- OR1N2 | c.606C>T p.I202= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as COSV65460782, COSV65460829; called by muse, mutect2
- OR6Y1 | c.963G>A p.G321= | Silent (SNP) | VAF 40/66 reads (61%) | called by muse, mutect2, varscan2
- OSBP | c.1629C>T p.I543= | Silent (SNP) | VAF 24/39 reads (62%) | called by muse, mutect2, varscan2
- P2RY10 | c.696C>T p.F232= | Silent (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- PCDHB6 | c.396C>T p.F132= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV50689941; called by muse, mutect2, varscan2
- PCDHGB5 | c.1791C>T p.N597= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs1163309827; called by muse, mutect2, varscan2
- PIGN | c.48C>T p.F16= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs148669516; called by muse, mutect2, varscan2
- PLB1 | c.3042C>T p.A1014= | Silent (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- PRAMEF4 | c.723C>T p.L241= | Silent (SNP) | VAF 115/305 reads (38%) | called by muse, mutect2, varscan2
- PRDM1 | c.891C>T p.V297= | Silent (SNP) | VAF 38/182 reads (21%) | called by muse, mutect2, varscan2
- PRPF4B | c.1578C>T p.D526= | Silent (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- PRRC2A | c.6159G>A p.V2053= | Silent (SNP) | VAF 35/142 reads (25%) | called by muse, mutect2, varscan2
- PRSS35 | c.549G>A p.K183= | Silent (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- RRAGB | c.558G>A p.L186= (on ENST00000262850 / NM_016656.4; = p.L158= on NM_006064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- SDK1 | c.6486C>T p.G2162= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- SLCO3A1 | c.285C>T p.F95= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV59237279; called by muse, mutect2, varscan2
- STH | c.177C>T p.T59= | Silent (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- TAS2R60 | c.360G>A p.V120= | Silent (SNP) | VAF 54/215 reads (25%) | catalogued as COSV60330157; called by muse, mutect2, varscan2
- TBC1D21 | c.54C>T p.F18= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs1351344047, COSV55996013; called by muse, mutect2, varscan2
- TG | c.7263C>T p.A2421= | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as rs146692559; called by muse, mutect2, varscan2
- TMC7 | c.1827C>T p.I609= | Silent (SNP) | VAF 60/215 reads (28%) | catalogued as rs1328156527; called by muse, mutect2, varscan2
- TTN | c.47793G>A p.G15931= (on ENST00000591111; = p.G8507= on NM_003319.4) | Silent (SNP) | VAF 13/19 reads (68%) | catalogued as rs369877063; called by muse, mutect2, varscan2
- UMODL1 | c.2244G>A p.E748= (on ENST00000408910 / NM_001004416.2; = p.E876= on NM_173568.3) | Silent (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- WDR72 | c.2136C>T p.V712= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV100854456; called by muse, mutect2, varscan2
- ZBTB32 | c.1231C>A p.R411= | Silent (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- ZFHX4 | c.9606C>T p.I3202= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV50490279; called by muse, mutect2, varscan2
- ZNF138 | c.357A>G p.G119= (on ENST00000307355 / NM_001367572.1; = p.G93= on NM_006524.4) | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as rs1205751278, COSV56465639; called by muse, mutect2, varscan2
- ZNF536 | c.2271G>A p.G757= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV62819373; called by muse, mutect2, varscan2
- HMGB1P1 | n.184G>A | RNA (SNP) | VAF 36/156 reads (23%) | called by muse, mutect2, varscan2
- TTN | c.10361-5504C>T | Intron (SNP) | VAF 25/70 reads (36%) | catalogued as rs867476348, COSV60114103; called by muse, mutect2, varscan2
